TCGA case TCGA-EL-A4K1 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa6e3437-ea1c-4bed-ab7d-8f3f89f8ceeb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.0 years (24,846 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,046 days (2.9 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 5; Measurement unit: Centimeters; Tumor depth measurement: 2; Tumor length measurement: 3.4; Tumor width measurement: 2.4.
   Recorded as not given: adjuvant I-131 Radiation Therapy; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 596 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 1,046 days (2.9 years); Disease response: Tumor Free.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EL-A4K1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 200 mg.
  Slide TCGA-EL-A4K1-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-EL-A4K1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EL-A4K1-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 240 mg.
  Slide TCGA-EL-A4K1-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 70; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; I 131 radiation first treatment method: Patient did not receive I-131 treatment; New tumor event diagnosis indicator: No.
- Neoplasm dimension: Tumor size width: 2.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: Patient did not receive I-131 treatment; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,046 days; disease-specific survival: no event (censored), 1,046 days; disease-free interval: no event (censored), 1,046 days; progression-free interval: no event (censored), 1,046 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EL-A4K1-01A-11D-A256-01): tumor purity 0.96, ploidy 2, whole-genome doublings 0.
